Somatic mutation profile of tumor specimen TCGA-39-5022-01A (aliquot TCGA-39-5022-01A-21D-1817-08) from TCGA case TCGA-39-5022, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 76.3 years (27,856 days).
Specimen TCGA-39-5022-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e0eeb84a-092c-473e-95bf-df788968c187.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-39-5022-11A (Solid Tissue Normal), aliquot TCGA-39-5022-11A-01D-1817-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c736579a-db0a-43ee-a151-718c69b7c03c

The open-access MAF lists 186 somatic variants for this specimen: 145 protein-altering or splice-affecting, 36 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 131, Silent 36, Nonsense Mutation 8, Intron 3, Splice Region 2, 5'UTR 1, Frame Shift Ins 1, Translation Start Site 1, Frame Shift Del 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.235G>C p.E79Q | Missense Mutation (SNP) | VAF 11/109 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519922, COSV67959999, COSV67960008, COSV67960140; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.3333T>A p.C1111* | Nonsense Mutation (SNP) | VAF 12/88 reads (14%) | catalogued as COSV66070350; called by muse, mutect2, varscan2
- ABCF3 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 57/183 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV53050143; called by muse, mutect2, varscan2
- ABCF3 | c.489G>C p.K163N | Missense Mutation (SNP) | VAF 89/228 reads (39%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.704); catalogued as COSV53050146; called by muse, mutect2, varscan2
- ABCF3 | c.1324G>A p.D442N | Missense Mutation (SNP) | VAF 68/205 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.737); catalogued as COSV53054285, COSV99491734; called by muse, mutect2, varscan2
- ABCG4 | c.1481C>T p.T494M | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201390504; called by muse, mutect2, varscan2
- AC098582.1 | c.658G>A p.G220R | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52018813; called by muse, mutect2
- ACAA2 | c.289C>G p.Q97E | Missense Mutation (SNP) | VAF 6/175 reads (3%) | SIFT tolerated (0.2); PolyPhen benign (0.268); catalogued as COSV53272261; called by muse, mutect2
- ADAMTS8 | c.841G>C p.E281Q | Missense Mutation (SNP) | VAF 11/305 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.044); catalogued as COSV57295161, COSV57297478; called by muse, mutect2
- ADH4 | c.450T>A p.S150R | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55502273; called by muse, mutect2, varscan2
- AMOTL2 | c.1276C>T p.Q426* | Nonsense Mutation (SNP) | VAF 11/146 reads (8%) | catalogued as COSV51440833; called by muse, mutect2
- APAF1 | c.2135A>G p.H712R (on ENST00000551964 / NM_181861.2; = p.H701R on NM_001160.3) | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1345151023, COSV59668296; called by muse, mutect2, varscan2
- APC2 | c.145G>A p.V49I | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1466107661, COSV52021963; called by muse, mutect2
- ARHGAP25 | c.1009C>A p.P337T (on ENST00000409202 / NM_001007231.3; = p.P329T on NM_014882.3) | Missense Mutation (SNP) | VAF 25/398 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.679); catalogued as COSV54908806; called by muse, mutect2
- ASPG | c.1004C>T p.S335L | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as rs987160415, COSV71933878; called by muse, mutect2, varscan2
- ATP10B | c.2160G>C p.E720D | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV59164061; called by muse, mutect2
- ATP1A3 | c.64G>C p.D22H (on ENST00000545399 / NM_001256214.2; = p.D9H on NM_152296.5) | Missense Mutation (SNP) | VAF 19/278 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.182); catalogued as COSV57491111; called by muse, mutect2
- BCAR3 | c.1003G>C p.A335P | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as COSV53079259; called by muse, mutect2
- BMP4 | c.463T>G p.S155A | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.72); PolyPhen benign (0.17); catalogued as COSV55417218; called by muse, mutect2, varscan2
- BPIFA3 | c.613G>C p.E205Q | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.966); catalogued as COSV64926245; called by muse, mutect2
- C1orf116 | c.718G>C p.E240Q | Missense Mutation (SNP) | VAF 10/350 reads (3%) | SIFT tolerated (0.16); PolyPhen benign (0.165); catalogued as COSV63944701; called by muse, mutect2
- C2CD3 | c.3565G>C p.E1189Q | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.637); catalogued as COSV58100638; called by muse, mutect2, varscan2
- C9 | c.1306T>A p.Y436N | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.643); catalogued as COSV54681403; called by muse, mutect2, varscan2
- CABCOCO1 | c.298G>C p.E100Q | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57596062; called by muse, mutect2, varscan2
- CASP8 | c.1124C>G p.S375* (on ENST00000432109 / NM_033355.3; = p.S392* on NM_001228.4) | Nonsense Mutation (SNP) | VAF 12/138 reads (9%) | catalogued as COSV51851118, COSV51852448; called by muse, mutect2
- CD79A | c.205G>A p.V69I | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT tolerated (0.95); PolyPhen benign (0.011); catalogued as rs782563209, COSV55738161; called by muse, mutect2, varscan2
- CDHR1 | c.233G>C p.R78T | Missense Mutation (SNP) | VAF 8/133 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.248); catalogued as COSV60562269, COSV60566278; called by muse, mutect2
- CETN1 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV59121518; called by muse, mutect2
- COL22A1 | c.1036G>A p.A346T | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV57359411; called by muse, mutect2
- COL6A6 | c.1409C>T p.P470L | Missense Mutation (SNP) | VAF 19/229 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV62036639; called by muse, mutect2
- CRB2 | c.1283C>T p.P428L | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV63505413; called by muse, mutect2
- CYC1 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.994); catalogued as COSV100010514; called by muse, mutect2
- DMD | c.5782G>T p.A1928S | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.163); catalogued as COSV63789820; called by muse, mutect2, varscan2
- DOCK3 | c.4177G>C p.E1393Q | Missense Mutation (SNP) | VAF 6/144 reads (4%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.557); catalogued as COSV56548701; called by muse, mutect2
- DOCK8 | c.1772G>C p.G591A | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as rs974686040, COSV66623826; called by muse, mutect2
- DPYSL5 | c.1483G>T p.D495Y | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as rs1344924718, COSV56513189, COSV56516012; called by muse, mutect2, varscan2
- DST | c.9139A>G p.T3047A | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.003); catalogued as COSV99758291; called by muse, mutect2
- DYNC1H1 | c.13452G>C p.E4484D | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.037); catalogued as COSV64142126; called by muse, mutect2
- ELOA2 | c.1358C>T p.T453M | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV55296340; called by muse, mutect2, varscan2
- ENGASE | c.456C>G p.F152L | Missense Mutation (SNP) | VAF 26/312 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as COSV56137717; called by muse, mutect2
- ERAL1 | c.95C>A p.P32H | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.343); catalogued as COSV54740953; called by muse, mutect2, varscan2
- FAM162B | c.217G>T p.D73Y | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63920632, COSV63920791; called by muse, mutect2
- FAM193A | c.2920G>C p.E974Q | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.889); catalogued as COSV61198575; called by muse, mutect2, varscan2
- FAM47C | c.2501G>T p.S834I | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); catalogued as COSV63730214; called by muse, mutect2, varscan2
- FAT1 | c.7349C>G p.S2450* | Nonsense Mutation (SNP) | VAF 24/261 reads (9%) | catalogued as COSV71673814, COSV71675311; called by muse, mutect2, varscan2
- FAT4 | c.6116T>C p.I2039T | Missense Mutation (SNP) | VAF 22/207 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as COSV58707717; called by muse, mutect2, varscan2
- FBN1 | c.634A>G p.T212A | Missense Mutation (SNP) | VAF 25/212 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57329621; called by muse, mutect2, varscan2
- FOXP2 | c.837G>C p.M279I | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV63491535, COSV63493664; called by muse, mutect2, varscan2
- GAS7 | c.205C>T p.P69S (on ENST00000432992 / NM_201433.2; = p.P9S on NM_201432.2) | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.77); PolyPhen benign (0.011); catalogued as COSV60443535; called by muse, mutect2, varscan2
- GLT6D1 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65628455; called by muse, mutect2
- GRIK4 | c.1147A>G p.R383G | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV70807039; called by muse, mutect2, varscan2
- GRXCR1 | c.213T>G p.D71E | Missense Mutation (SNP) | VAF 19/214 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV67674581; called by muse, mutect2
- GSTZ1 | c.396G>C p.Q132H | Missense Mutation (SNP) | VAF 8/133 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV53624532; called by muse, mutect2
- HELZ | c.2175C>G p.L725= | Splice Region (SNP) | VAF 5/65 reads (8%) | catalogued as COSV62377400; called by muse, mutect2
- HELZ | c.965C>T p.S322L | Missense Mutation (SNP) | VAF 11/349 reads (3%) | SIFT tolerated (0.49); PolyPhen benign (0.013); catalogued as COSV62380855; called by muse, mutect2
- HIP1 | c.1570G>T p.G524C | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as COSV61191309; called by muse, mutect2
- HMGB4 | c.70A>G p.R24G | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.516); catalogued as COSV53959607; called by muse, mutect2
- IGHE | c.1226A>G p.H409R | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200204014; called by muse, mutect2, varscan2
- INSIG1 | c.658C>G p.L220V | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.103); catalogued as COSV60919643, COSV60921239; called by muse, mutect2
- IQUB | c.469C>G p.L157V | Missense Mutation (SNP) | VAF 30/310 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV61242625; called by muse, mutect2
- KALRN | c.1566G>C p.E522D | Missense Mutation (SNP) | VAF 4/102 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV53779634; called by muse, mutect2
- KRT14 | c.1316G>C p.R439T | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.036); catalogued as COSV51423133; called by muse, mutect2
- KRT31 | c.50C>G p.S17C | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.319); catalogued as COSV52438494; called by muse, mutect2, varscan2
- KRTAP10-5 | c.500C>A p.P167H | Missense Mutation (SNP) | VAF 14/261 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV100552456, COSV59979014; called by muse, mutect2
- LAIR1 | c.627-1G>T p.X209_splice | Splice Site (SNP) | VAF 14/67 reads (21%) | catalogued as COSV57309786; called by muse, mutect2, varscan2
- LAMA4 | c.4309_4310insA p.P1437Hfs*28 (on ENST00000230538 / NM_001105206.3; = p.P1430Hfs*28 on NM_002290.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 6/58 reads (10%) | catalogued as COSV100038911; called by mutect2, pindel, varscan2
- LDB2 | c.772A>G p.R258G | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58781971; called by muse, mutect2, varscan2
- LIPI | c.189G>T p.E63D | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.036); catalogued as COSV60715934; called by muse, mutect2, varscan2
- LRP2 | c.5084C>T p.S1695L | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs767944750, COSV55573172; called by muse, mutect2, varscan2
- LTBR | c.893C>G p.S298C | Missense Mutation (SNP) | VAF 20/201 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV57439915; called by muse, mutect2
- LY75 | c.410C>G p.S137C | Missense Mutation (SNP) | VAF 6/144 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV55112667; called by muse, mutect2
- LYZL2 | c.141G>T p.M47I (on ENST00000375318; = p.M1? on NM_183058.3) | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV64684991; called by muse, mutect2
- MANBAL | c.96C>G p.F32L | Missense Mutation (SNP) | VAF 7/155 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV65311907; called by muse, mutect2
- MAP3K15 | c.1307G>C p.R436T | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100135206; called by muse, mutect2, varscan2
- MED12L | c.6122C>G p.S2041C | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.971); catalogued as COSV56396157; called by muse, mutect2
- MKI67 | c.7897C>G p.H2633D | Missense Mutation (SNP) | VAF 7/148 reads (5%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.675); catalogued as COSV64076790; called by muse, mutect2
- MLH3 | c.1516G>T p.E506* | Nonsense Mutation (SNP) | VAF 7/143 reads (5%) | catalogued as COSV53158837; called by muse, mutect2
- MME | c.1683G>T p.Q561H | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV64710669; called by muse, mutect2
- MOG | c.133G>A p.V45I | Missense Mutation (SNP) | VAF 75/287 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV65321069, COSV65321347; called by muse, mutect2, varscan2
- MYH8 | c.2629G>C p.E877Q | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as COSV67972088; called by muse, mutect2, varscan2
- MYLIP | c.118G>A p.D40N | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1328586380, COSV62767186, COSV62767636; called by muse, mutect2
- NAV3 | c.5677G>A p.E1893K (on ENST00000397909 / NM_001024383.2; = p.E1871K on NM_014903.6) | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV57110786; called by muse, mutect2, varscan2
- NRSN2 | c.449C>T p.P150L | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs1278887958, COSV66526617; called by muse, mutect2
- OR2L13 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 38/156 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs553614392, COSV63560530; called by muse, mutect2, varscan2
- OR4K14 | c.339G>T p.M113I | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.027); catalogued as COSV59294150; called by muse, mutect2, varscan2
- OR4S2 | c.64G>C p.E22Q | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV56748314; called by muse, mutect2, varscan2
- P2RY10 | c.904C>G p.P302A | Missense Mutation (SNP) | VAF 8/219 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV50685911, COSV99409411; called by muse, mutect2
- PCDH7 | c.2213A>G p.N738S | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as COSV62343290; called by muse, mutect2
- PCDHAC2 | c.131T>A p.L44Q | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as COSV53868408; called by muse, mutect2, varscan2
- PCDHB7 | c.1676C>A p.P559H | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50813372; called by muse, mutect2
- PCLO | c.2043G>T p.Q681H | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.045); catalogued as COSV61664168; called by muse, mutect2
- PEG3 | c.3297G>T p.K1099N | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.079); catalogued as rs753462267, COSV55646735; called by muse, mutect2
- PIP5K1A | c.95G>T p.G32V (on ENST00000368888 / NM_001135638.2; = p.G31V on NM_003557.3) | Missense Mutation (SNP) | VAF 9/230 reads (4%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.123); catalogued as COSV62960041; called by muse, mutect2
- PKHD1 | c.3125C>T p.S1042F | Missense Mutation (SNP) | VAF 13/171 reads (8%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.852); catalogued as COSV61893910; called by muse, mutect2
- PLEKHM3 | c.985C>T p.H329Y | Missense Mutation (SNP) | VAF 11/143 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV66818677; called by muse, mutect2
- POGLUT3 | c.1314G>C p.K438N | Missense Mutation (SNP) | VAF 17/170 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.068); catalogued as COSV60213119; called by muse, mutect2
- PTGES3L-AARSD1 | c.424G>A p.D142N (on ENST00000421990 / NM_001136042.2; = p.D124N on NM_025267.3) | Missense Mutation (SNP) | VAF 54/571 reads (9%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.947); catalogued as COSV64183745, COSV64184528; called by muse, mutect2
- PXMP4 | c.551C>A p.S184Y | Missense Mutation (SNP) | VAF 25/216 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV54134496; called by muse, mutect2, varscan2
- PYGM | c.2468G>T p.R823L | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.144); catalogued as COSV51227148; called by muse, mutect2, varscan2
- RAPH1 | c.2098C>T p.Q700* | Nonsense Mutation (SNP) | VAF 12/75 reads (16%) | catalogued as COSV55589284; called by muse, mutect2, varscan2
- RELN | c.1996G>C p.D666H | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100633888, COSV59032627; called by muse, mutect2, varscan2
- RNF121 | c.91G>C p.E31Q | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.756); catalogued as COSV62316883, COSV62317376; called by muse, mutect2, varscan2
- RNF145 | c.1985C>T p.S662L (on ENST00000424310 / NM_001199383.2; = p.S690L on NM_144726.2) | Missense Mutation (SNP) | VAF 20/266 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.01); catalogued as COSV50872341; called by muse, mutect2
- RYR2 | c.10567G>A p.A3523T | Missense Mutation (SNP) | VAF 60/289 reads (21%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.853); catalogued as rs1206114481, COSV63712258; called by muse, mutect2, varscan2
- SIGLEC10 | c.1718T>G p.I573S | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as COSV59486419; called by muse, varscan2
- SLC44A5 | c.307C>T p.P103S | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.248); catalogued as COSV63774480; called by muse, mutect2
- SLX4IP | c.445G>C p.E149Q | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.243); catalogued as COSV57951233; called by muse, mutect2
- SMAP2 | c.637C>G p.L213V | Missense Mutation (SNP) | VAF 22/450 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV65534209; called by muse, mutect2
- SOGA3 | c.113G>A p.R38Q | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV64108577; called by muse, mutect2, varscan2
- SPG11 | c.3872G>C p.S1291T | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as COSV56001690, COSV99968247; called by muse, mutect2
- SPOP | c.583G>T p.E195* | Nonsense Mutation (SNP) | VAF 53/294 reads (18%) | catalogued as COSV61655716; called by muse, mutect2, varscan2
- SRRM2 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 10/129 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV57080203; called by muse, mutect2
- STAB2 | c.911A>T p.H304L | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.548); catalogued as COSV66346538; called by muse, mutect2
- STX19 | c.835C>A p.P279T | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV57401444; called by mutect2, varscan2
- SUN5 | c.135G>A p.M45I | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.011); catalogued as COSV50070406; called by muse, mutect2
- SYTL1 | c.508G>C p.E170Q (on ENST00000543823; = p.E158Q on NM_032872.3) | Missense Mutation (SNP) | VAF 7/125 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV58874442; called by muse, mutect2
- TAF1B | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV55154416, COSV55156165; called by muse, mutect2
- TAF1L | c.1192T>C p.S398P | Missense Mutation (SNP) | VAF 34/234 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV54268746; called by muse, mutect2, varscan2
- TBC1D21 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 4/31 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.577); catalogued as COSV55996709; called by muse, mutect2
- TBC1D8B | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.354); catalogued as COSV52176621; called by muse, mutect2, varscan2
- TBX18 | c.1543C>T p.Q515* | Nonsense Mutation (SNP) | VAF 15/285 reads (5%) | catalogued as COSV63736201, COSV63738217, COSV63738371; called by muse, mutect2
- TGM4 | c.1036T>C p.W346R | Missense Mutation (SNP) | VAF 12/157 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV56096398; called by muse, mutect2
- THSD7A | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 23/179 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as COSV70260711; called by muse, mutect2, varscan2
- TIMD4 | c.5C>G p.S2C | Missense Mutation (SNP) | VAF 17/179 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV50859876; called by muse, mutect2
- TMEM244 | c.170C>T p.S57L | Missense Mutation (SNP) | VAF 21/204 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV63743348; called by muse, mutect2
- TNFSF15 | c.599C>G p.S200C | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV65010974; called by muse, mutect2
- TNS1 | c.1533C>G p.H511Q | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV50763881; called by muse, mutect2, varscan2
- TRPC4AP | c.1593C>T p.F531= | Splice Region (SNP) | VAF 13/182 reads (7%) | catalogued as COSV52684338; called by muse, mutect2
- TSSC4 | c.617C>G p.S206C | Missense Mutation (SNP) | VAF 4/98 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50190927; called by muse, mutect2
- TSSK6 | c.58G>C p.E20Q | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.091); catalogued as COSV53064159, COSV53065231; called by muse, mutect2
- TUBA3E | c.560C>T p.S187F | Missense Mutation (SNP) | VAF 26/256 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV56058814; called by muse, mutect2
- UCP1 | c.221T>A p.L74H | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV53768645; called by muse, mutect2
- USP34 | c.8302G>C p.E2768Q | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV68406255; called by muse, mutect2, varscan2
- VMP1 | c.579G>C p.M193I | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.692); catalogued as COSV51872282, COSV99230987; called by muse, mutect2, varscan2
- VWA7 | c.2329C>T p.H777Y | Missense Mutation (SNP) | VAF 14/189 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as COSV65174141; called by muse, mutect2
- XRCC6 | c.1288C>G p.P430A | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.418); catalogued as rs1168219605, COSV63753750; called by muse, mutect2
- YEATS2 | c.336C>G p.I112M | Missense Mutation (SNP) | VAF 11/313 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV59372234; called by muse, mutect2
- ZFHX3 | c.1721G>C p.S574T | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.011); catalogued as COSV51713864, COSV51734821; called by muse, mutect2, varscan2
- ZNF341 | c.433A>T p.M145L | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as COSV61011143; called by muse, mutect2, varscan2
- ZNF346 | c.540G>C p.M180I | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV56158177; called by muse, mutect2, varscan2
- ZNF616 | c.2297G>C p.R766T | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV57509717; called by muse, mutect2
- ZNF875 | c.782T>C p.L261P | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.424); catalogued as COSV60992263, COSV60993694; called by muse, mutect2
- ZNF91 | c.1793G>T p.G598V | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV56092550; called by muse, mutect2, varscan2
- IGHV3-74 | c.182G>T p.G61V | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- TP53 | c.136_152del p.S46Tfs*5 | Frame Shift Del (DEL) | VAF 52/362 reads (14%) | called by mutect2, pindel
- ABRAXAS2 | c.1005A>G p.Q335= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as rs775860704, COSV53718425; called by muse, mutect2, varscan2
- AHDC1 | c.1584G>C p.R528= | Silent (SNP) | VAF 5/101 reads (5%) | catalogued as COSV55942235; called by muse, mutect2
- ARHGAP20 | c.519G>A p.K173= | Silent (SNP) | VAF 17/109 reads (16%) | catalogued as COSV52818929; called by muse, mutect2, varscan2
- CARD6 | c.1413C>G p.L471= | Silent (SNP) | VAF 14/148 reads (9%) | catalogued as COSV54568951; called by muse, mutect2, varscan2
- CCDC102B | c.390G>T p.A130= | Silent (SNP) | VAF 17/98 reads (17%) | catalogued as COSV60153600; called by muse, mutect2, varscan2
- CD58 | c.78C>T p.I26= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as rs754340222, COSV65665410; called by muse, mutect2, varscan2
- CDCP1 | c.747C>T p.L249= | Silent (SNP) | VAF 14/230 reads (6%) | catalogued as COSV56107917; called by muse, mutect2
- CHRNB2 | c.204C>T p.I68= | Silent (SNP) | VAF 9/83 reads (11%) | catalogued as COSV63809395; called by muse, mutect2
- CRISP3 | c.171C>A p.P57= (on ENST00000371159 / NM_001368123.1; = p.P39= on NM_006061.4) | Silent (SNP) | VAF 40/246 reads (16%) | catalogued as COSV53819965, COSV53820909; called by muse, mutect2, varscan2
- DDX60L | c.4026G>C p.L1342= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV52721526; called by muse, mutect2, varscan2
- EGR3 | c.732C>A p.G244= | Silent (SNP) | VAF 14/125 reads (11%) | catalogued as COSV57834454; called by muse, mutect2, varscan2
- ESRRB | c.507G>A p.L169= | Silent (SNP) | VAF 14/330 reads (4%) | catalogued as COSV55066990; called by muse, mutect2
- ETV6 | c.1056C>T p.S352= | Silent (SNP) | VAF 12/187 reads (6%) | catalogued as COSV56766801; called by muse, mutect2
- GABRA2 | c.795C>A p.V265= | Silent (SNP) | VAF 8/106 reads (8%) | catalogued as COSV100734579; called by muse, mutect2
- GJD2 | c.522G>T p.L174= | Silent (SNP) | VAF 28/241 reads (12%) | catalogued as COSV51749922; called by muse, mutect2, varscan2
- HPGDS | c.453C>T p.F151= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as COSV54775963; called by muse, mutect2, varscan2
- HS3ST1 | c.252G>A p.E84= | Silent (SNP) | VAF 12/88 reads (14%) | catalogued as COSV50026459; called by muse, mutect2, varscan2
- KCNH7 | c.327C>T p.N109= | Silent (SNP) | VAF 6/80 reads (8%) | catalogued as COSV59812823; called by muse, mutect2
- KIAA1217 | c.1707G>A p.Q569= | Silent (SNP) | VAF 5/102 reads (5%) | catalogued as COSV56823452; called by muse, mutect2
- MIA3 | c.4567C>T p.L1523= | Silent (SNP) | VAF 6/109 reads (6%) | catalogued as COSV60509406, COSV60512436; called by muse, mutect2
- MUC16 | c.14511C>A p.T4837= | Silent (SNP) | VAF 17/126 reads (13%) | catalogued as COSV67491799; called by muse, mutect2
- NT5C1B | c.165C>G p.P55= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs757547617, COSV58398902; called by mutect2, varscan2
- OTP | c.306G>A p.Q102= | Silent (SNP) | VAF 10/182 reads (5%) | catalogued as COSV60569893; called by muse, mutect2
- RASGEF1A | c.819G>C p.L273= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV65667480; called by muse, mutect2, varscan2
- SIDT2 | c.2445G>C p.L815= | Silent (SNP) | VAF 16/206 reads (8%) | catalogued as COSV54060650, COSV54061365; called by muse, mutect2
- SIGLEC14 | c.309G>A p.L103= | Silent (SNP) | VAF 18/479 reads (4%) | catalogued as COSV99707717; called by muse, mutect2
- SLC17A6 | c.438G>T p.A146= | Silent (SNP) | VAF 20/120 reads (17%) | catalogued as COSV54141136; called by muse, mutect2, varscan2
- SLC7A14 | c.1821G>A p.L607= | Silent (SNP) | VAF 7/148 reads (5%) | catalogued as COSV51589709; called by muse, mutect2
- SPTB | c.4368C>T p.I1456= | Silent (SNP) | VAF 7/189 reads (4%) | catalogued as rs1204164201, COSV67630329; called by muse, mutect2
- TAS1R2 | c.1473T>A p.P491= | Silent (SNP) | VAF 16/137 reads (12%) | catalogued as COSV64747144; called by muse, mutect2, varscan2
- TEKT1 | c.561C>T p.I187= | Silent (SNP) | VAF 19/202 reads (9%) | catalogued as COSV58622268, COSV58623702; called by muse, mutect2
- TLR4 | c.2076A>G p.L692= (on ENST00000355622 / NM_138554.5; = p.L652= on NM_003266.4) | Silent (SNP) | VAF 17/117 reads (15%) | catalogued as COSV62924191; called by muse, mutect2, varscan2
- TMEM94 | c.2016C>G p.L672= | Silent (SNP) | VAF 17/82 reads (21%) | catalogued as COSV58599741; called by muse, mutect2, varscan2
- TNFAIP6 | c.60C>T p.F20= | Silent (SNP) | VAF 12/138 reads (9%) | catalogued as COSV54642581; called by muse, mutect2
- TRUB2 | c.105G>C p.L35= | Silent (SNP) | VAF 7/92 reads (8%) | catalogued as COSV55957951; called by muse, mutect2
- TTC37 | c.2277C>G p.L759= | Silent (SNP) | VAF 6/61 reads (10%) | catalogued as COSV62456808; called by muse, mutect2, varscan2
- IL7R | c.-2G>C | 5'UTR (SNP) | VAF 7/158 reads (4%) | catalogued as COSV100286440; called by muse, mutect2
- MIR1-1HG-AS1 | n.508C>G | RNA (SNP) | VAF 11/186 reads (6%) | catalogued as rs782400148; called by muse, mutect2
- NOP58 | c.122+1286T>A | Intron (SNP) | VAF 6/45 reads (13%) | catalogued as COSV99970737; called by muse, mutect2, varscan2
- SMOC2 | c.512-10C>A | Intron (SNP) | VAF 10/179 reads (6%) | catalogued as COSV100635319, COSV62444137; called by muse, mutect2
- TTBK2 | c.823-6927G>T | Intron (SNP) | VAF 22/147 reads (15%) | called by muse, mutect2, varscan2
